Somatic mutation profile of tumor specimen TCGA-44-2668-01A (aliquot TCGA-44-2668-01A-01D-0969-08) from TCGA case TCGA-44-2668, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.6 years (18,856 days).
Specimen TCGA-44-2668-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9325ca35-d167-465e-a582-7991f67f713a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2668-10A (Blood Derived Normal), aliquot TCGA-44-2668-10A-01D-1489-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73ba80a3-a225-4bbb-a2cc-ddf898f41ec6

The open-access MAF lists 415 somatic variants for this specimen: 314 protein-altering or splice-affecting, 99 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 259, Silent 99, Nonsense Mutation 29, Splice Site 11, Frame Shift Del 9, Splice Region 2, 5'Flank 1, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INS-IGF2 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs80356664, CM074280, CM074281, CM1314526, COSV51747478; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 19/183 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893810, CM050761, CM140638, COSV55443375, COSV55461069, COSV99848566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | hotspot (GDC flag); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACER2 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61820950; called by muse, mutect2, varscan2
- ADAMTS19 | c.1002G>C p.E334D | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50757482; called by muse, mutect2, varscan2
- ADAMTS20 | c.4640G>A p.C1547Y | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV67133587; called by muse, mutect2, varscan2
- ADAMTS4 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 39/351 reads (11%) | catalogued as COSV63488058; called by muse, mutect2, varscan2
- ADCY2 | c.982-1G>T p.X328_splice | Splice Site (SNP) | VAF 72/345 reads (21%) | catalogued as COSV57879098; called by muse, mutect2, varscan2
- ADGRB3 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV65401825; called by muse, mutect2, varscan2
- ADGRE1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV51677006; called by muse, mutect2
- AFF2 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60669144; called by mutect2, varscan2
- AHI1 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV55629204; called by muse, mutect2
- AKAP1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs756461688, COSV58470959; called by muse, mutect2, varscan2
- AMOT | c.2416A>T p.T806S (on ENST00000371959 / NM_001113490.1; = p.T397S on NM_133265.3) | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV59064774; called by muse, mutect2, varscan2
- ANGEL1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1356414829, COSV51873956; called by muse, mutect2, varscan2
- ANGPT4 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67921955; called by muse, mutect2, varscan2
- ANK2 | c.9628A>G p.T3210A | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV52168144; called by muse, mutect2, varscan2
- ANKFN1 | c.1624C>G p.H542D | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.169); catalogued as COSV59450694; called by muse, mutect2
- ANKH | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52482285, COSV99414490; called by muse, mutect2, varscan2
- AOC3 | c.606G>T p.K202N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53827372; called by muse, mutect2, varscan2
- AQP10 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59246622; called by muse, mutect2
- ARGLU1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62271695, COSV62271857; called by muse, mutect2, varscan2
- ARHGEF7 | c.988G>T p.V330L (on ENST00000375741 / NM_001113511.2; = p.V152L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as rs752939884, COSV54545313, COSV54549428; called by muse, mutect2, varscan2
- ARHGEF7 | c.1533G>C p.L511F (on ENST00000375741 / NM_001113511.2; = p.L333F on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54545336; called by muse, mutect2, varscan2
- ASIC4 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV61732282; called by muse, mutect2, varscan2
- ASXL3 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV52469738; called by muse, mutect2, varscan2
- ATR | c.6480G>C p.L2160F | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63384624; called by muse, mutect2
- BCHE | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV52258139; called by muse, mutect2, varscan2
- BEST4 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 56/443 reads (13%) | catalogued as rs138830699; called by muse, mutect2, varscan2
- BMP10 | c.631del p.Q211Kfs*29 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | catalogued as COSV54895014; called by mutect2, pindel, varscan2
- BTN2A1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201411917, COSV57004085; called by muse, mutect2, varscan2
- C10orf90 | c.1908C>G p.F636L | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52956156, COSV52957468; called by muse, mutect2, varscan2
- C11orf45 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as rs908201035, COSV57967286; called by muse, mutect2
- C4orf17 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.792); catalogued as COSV58512810; called by muse, mutect2
- C9orf64 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 29/149 reads (19%) | catalogued as COSV59032715; called by muse, mutect2, varscan2
- CACNA1H | c.6677del p.T2226Sfs*36 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as COSV52352653; called by mutect2, pindel, varscan2
- CASP4 | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67744530; called by muse, mutect2, varscan2
- CCDC178 | c.2148G>C p.E716D (on ENST00000383096 / NM_001105528.3; = p.E678D on NM_198995.3) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV55778957; called by muse, mutect2, varscan2
- CCDC28A | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs143442772; called by muse, mutect2, varscan2
- CCDC57 | c.719G>T p.R240M | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV66433924, COSV66434564; called by muse, mutect2, varscan2
- CD200R1 | c.307G>T p.E103* (on ENST00000471858 / NM_170780.3; = p.E126* on NM_138806.4) | Nonsense Mutation (SNP) | VAF 52/230 reads (23%) | catalogued as COSV55601504; called by muse, mutect2, varscan2
- CDH10 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV52584948; called by muse, mutect2, varscan2
- CDH6 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54071180, COSV54072095; called by muse, mutect2, varscan2
- CDH6 | c.1907T>A p.L636Q | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV54072103; called by muse, mutect2, varscan2
- CDH7 | c.2191C>A p.Q731K | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59888138; called by muse, mutect2, varscan2
- CEP20 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); catalogued as COSV55384481; called by muse, mutect2, varscan2
- CFI | c.1045-2A>T p.X349_splice | Splice Site (SNP) | VAF 54/380 reads (14%) | catalogued as COSV67098982; called by muse, mutect2, varscan2
- CHD4 | c.3520G>C p.V1174L (on ENST00000357008 / NM_001363606.2; = p.V1187L on NM_001273.5) | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as COSV58903691; called by muse, mutect2
- CHD8 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.428); catalogued as COSV101303091; called by muse, mutect2
- CHD9 | c.5581A>T p.R1861* | Nonsense Mutation (SNP) | VAF 45/189 reads (24%) | catalogued as COSV54611874; called by muse, mutect2, varscan2
- CHRM3 | c.1592G>C p.W531S | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55104940, COSV99697990; called by muse, mutect2, varscan2
- CHRM3 | c.1593G>T p.W531C | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55108107, COSV99697992; called by muse, mutect2, varscan2
- CLRN2 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV72512587; called by muse, mutect2, varscan2
- CNTN3 | c.2944G>C p.D982H | Missense Mutation (SNP) | VAF 65/455 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV55175046; called by muse, mutect2, varscan2
- CNTNAP2 | c.1075T>G p.S359A | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.184); catalogued as COSV62201650; called by muse, mutect2, varscan2
- COBL | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.386); catalogued as COSV54348893; called by muse, mutect2, varscan2
- COG5 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV51754667; called by muse, mutect2, varscan2
- COL22A1 | c.3914C>G p.P1305R | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV100279666, COSV57342867; called by muse, mutect2, varscan2
- COL24A1 | c.2656del p.E886Kfs*50 | Frame Shift Del (DEL) | VAF 56/389 reads (14%) | catalogued as COSV65304056; called by mutect2, pindel, varscan2
- COL24A1 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as COSV100992999, COSV65308229; called by muse, mutect2, varscan2
- COL4A6 | c.2780G>T p.G927V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57859421, COSV57869363; called by muse, mutect2, varscan2
- COL4A6 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57869376; called by muse, mutect2, varscan2
- COL6A3 | c.1631G>T p.R544L | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780201464, COSV55094333; called by muse, mutect2, varscan2
- CRLF1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as rs142326326; called by muse, mutect2, varscan2
- CSDE1 | c.1717A>G p.K573E (on ENST00000358528 / NM_001007553.3; = p.K542E on NM_007158.6) | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54750316; called by muse, mutect2
- CSMD3 | c.8710G>C p.G2904R (on ENST00000297405 / NM_001363185.1; = p.G2735R on NM_052900.3) | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52213938; called by muse, mutect2
- CSMD3 | c.1300C>A p.Q434K | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.761); catalogued as COSV52213955; called by muse, mutect2, varscan2
- CSMD3 | c.760A>T p.S254C | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV52213979; called by muse, mutect2, varscan2
- CSNK1D | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV58365102; called by muse, mutect2
- CYP4F2 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV50001627; called by muse, mutect2, varscan2
- DCT | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV65469687; called by muse, mutect2, varscan2
- DDX11 | c.1955T>G p.V652G | Missense Mutation (SNP) | VAF 69/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52506006, COSV52507585; called by muse, mutect2, varscan2
- DDX49 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); catalogued as rs749236961, COSV53231010; called by muse, mutect2, varscan2
- DERL1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52365157; called by muse, varscan2
- DHRSX | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 24/218 reads (11%) | catalogued as COSV58135095; called by muse, mutect2, varscan2
- DHTKD1 | c.1356C>G p.I452M | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53804398, COSV53806440; called by muse, mutect2
- DHX32 | c.177A>T p.R59S | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52941025; called by muse, mutect2, varscan2
- DIAPH3 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57368044; called by muse, mutect2
- DLGAP2 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.147); catalogued as COSV70099886; called by muse, mutect2, varscan2
- DNAH1 | c.11593G>A p.D3865N | Missense Mutation (SNP) | VAF 59/346 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV56235798; called by muse, mutect2, varscan2
- DNAH2 | c.12385C>G p.L4129V | Missense Mutation (SNP) | VAF 27/397 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV66721080; called by muse, mutect2
- DNAH9 | c.796T>C p.Y266H | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV52356054; called by muse, mutect2, varscan2
- DNAH9 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201122944, COSV52356066; called by muse, mutect2, varscan2
- DPP6 | c.2512T>A p.S838T (on ENST00000377770 / NM_001364500.2; = p.S776T on NM_001936.5) | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.133); catalogued as COSV59622580; called by muse, varscan2
- DROSHA | c.854G>T p.R285I | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV60777911; called by muse, mutect2, varscan2
- DSC3 | c.631T>C p.L211= | Splice Region (SNP) | VAF 6/86 reads (7%) | catalogued as COSV64573557; called by muse, mutect2
- DUSP6 | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54378990; called by muse, mutect2, varscan2
- DYDC2 | c.31G>T p.G11* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | catalogued as COSV55472654; called by muse, mutect2, varscan2
- EIF2D | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55114118; called by muse, mutect2, varscan2
- EPHA4 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56036407; called by muse, mutect2, varscan2
- EPHA6 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67577491; called by muse, mutect2, varscan2
- ERICH3 | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58603768; called by muse, mutect2, varscan2
- ERICH3 | c.1850G>C p.R617T | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58609992, COSV58620417; called by muse, varscan2
- ERICH6 | c.1806G>C p.K602N | Missense Mutation (SNP) | VAF 64/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55799476, COSV55801319; called by muse, mutect2, varscan2
- ESD | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66340464, COSV66340808; called by muse, mutect2, varscan2
- F13A1 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161514, COSV53560791; called by muse, mutect2, varscan2
- FAAP24 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54280597; called by muse, mutect2, varscan2
- FAM124B | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 18/163 reads (11%) | catalogued as COSV66272581; called by muse, mutect2, varscan2
- FAM171A1 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65317027; called by muse, mutect2, varscan2
- FAM83B | c.2012C>A p.S671* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV60923240, COSV60928141; called by muse, mutect2, varscan2
- FANK1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.567); catalogued as rs141545587; called by muse, mutect2, varscan2
- FAT3 | c.5623G>A p.D1875N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.325); catalogued as COSV53127603; called by muse, mutect2, varscan2
- FAT4 | c.5533G>T p.V1845L | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.673); catalogued as COSV58691310, COSV58700791; called by muse, mutect2, varscan2
- FATE1 | c.265A>T p.R89* | Nonsense Mutation (SNP) | VAF 27/112 reads (24%) | catalogued as COSV64849047; called by muse, mutect2, varscan2
- FBN2 | c.1537A>T p.T513S | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV52496714; called by muse, mutect2, varscan2
- FBXO40 | c.1138A>T p.T380S | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57524928; called by muse, mutect2, varscan2
- FGF5 | c.723C>G p.S241R | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.015); catalogued as COSV56890586; called by muse, mutect2, varscan2
- FHOD3 | c.3458C>A p.S1153* (on ENST00000359247 / NM_001281739.3; = p.S1170* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 16/153 reads (10%) | catalogued as COSV57176969; called by muse, mutect2, varscan2
- FLG | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 9/178 reads (5%) | catalogued as COSV100911557, COSV64243248; called by muse, mutect2
- FLVCR2 | c.1464G>C p.K488N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV53162934; called by muse, mutect2
- FNDC1 | c.2791T>A p.S931T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV51940473; called by muse, mutect2, varscan2
- FRZB | c.479-2A>T p.X160_splice | Splice Site (SNP) | VAF 36/169 reads (21%) | catalogued as COSV54554602; called by muse, mutect2, varscan2
- GABBR2 | c.1124C>A p.T375K | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV52308181; called by muse, mutect2, varscan2
- GDF5 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV65501945; called by muse, mutect2, varscan2
- GFI1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.084); catalogued as rs776025480, COSV54043001; called by muse, mutect2, varscan2
- GFPT1 | c.1510G>T p.V504L (on ENST00000357308 / NM_001244710.2; = p.V486L on NM_002056.4) | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as COSV61948621; called by muse, mutect2, varscan2
- GLI1 | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.691); catalogued as rs267603605, COSV57363662; called by muse, mutect2, varscan2
- GLP2R | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52326159; called by muse, mutect2, varscan2
- GMIP | c.551A>T p.K184I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV52557322; called by muse, mutect2, varscan2
- GNA13 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.17); catalogued as COSV71474582, COSV71474880; called by muse, mutect2
- GRID2 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV56220748; called by muse, mutect2, varscan2
- GRID2 | c.2083G>T p.G695* | Nonsense Mutation (SNP) | VAF 15/130 reads (12%) | catalogued as COSV56178049, COSV56220754; called by muse, mutect2, varscan2
- GRK5 | c.1423A>T p.K475* | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as COSV64866728; called by muse, mutect2, varscan2
- GRM7 | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV63148841; called by muse, mutect2, varscan2
- GYS2 | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 35/364 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV53924634; called by muse, mutect2
- H3C12 | c.332G>C p.C111S | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV58152941; called by muse, mutect2, varscan2
- HBD | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV53082946, COSV53083332; called by muse, mutect2
- HCST | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 85/769 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV52887938; called by muse, mutect2, varscan2
- HOXD12 | c.627C>A p.Y209* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV66832685; called by muse, mutect2, varscan2
- IARS2 | c.2059A>G p.K687E | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.243); catalogued as COSV56960725; called by muse, mutect2
- IFI16 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55535430; called by muse, mutect2, varscan2
- IGHV3-20 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs782671152; called by muse, mutect2
- IMMT | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54480837; called by muse, mutect2, varscan2
- ITGA11 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59878749; called by muse, varscan2
- ITGA8 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65230549; called by muse, mutect2, varscan2
- ITGAX | c.2446G>T p.G816* | Nonsense Mutation (SNP) | VAF 34/226 reads (15%) | catalogued as COSV51647027, COSV51651894; called by muse, mutect2, varscan2
- ITGAX | c.2976+1G>T p.X992_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV51647036; called by muse, mutect2, varscan2
- ITPR1 | c.4798A>C p.I1600L (on ENST00000354582; = p.I1585L on NM_002222.7) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV56986846; called by muse, mutect2, varscan2
- KATNIP | c.4259G>T p.G1420V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265663435, COSV55183565; called by muse, mutect2, varscan2
- KCNK9 | c.157A>G p.N53D | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV57283067; called by muse, mutect2, varscan2
- KCNT2 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54086765, COSV54100416; called by muse, mutect2, varscan2
- KDM6B | c.2484del p.P829Lfs*65 | Frame Shift Del (DEL) | VAF 22/198 reads (11%) | catalogued as COSV54679083; called by mutect2, pindel, varscan2
- KMT2D | c.5837G>C p.G1946A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV56453057; called by muse, mutect2, varscan2
- KNDC1 | c.3977G>T p.W1326L | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58839924; called by muse, mutect2, varscan2
- KPNB1 | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51597852; called by muse, mutect2, varscan2
- KRTAP8-1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.983); catalogued as COSV61598105; called by muse, mutect2, varscan2
- LCE3E | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV64231901; called by muse, mutect2, varscan2
- LRRC15 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV61649919; called by muse, mutect2, varscan2
- LRRC6 | c.786G>T p.L262F | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV51543455; called by muse, mutect2, varscan2
- LRRN2 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV65784108; called by muse, mutect2, varscan2
- LTBP2 | c.830+1G>T p.X277_splice | Splice Site (SNP) | VAF 18/89 reads (20%) | catalogued as COSV56209738; called by muse, mutect2, varscan2
- LYPLAL1 | c.406A>T p.R136* | Nonsense Mutation (SNP) | VAF 26/143 reads (18%) | catalogued as COSV65106842; called by muse, mutect2, varscan2
- MARK1 | c.1630G>T p.V544F | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65068372; called by muse, mutect2, varscan2
- MAT1A | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64746039; called by muse, mutect2
- MCF2L2 | c.1501A>T p.K501* | Nonsense Mutation (SNP) | VAF 40/154 reads (26%) | catalogued as COSV61055553; called by muse, mutect2, varscan2
- MGAM | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV71885618; called by muse, mutect2, varscan2
- MGAT4A | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53847952; called by muse, mutect2
- MMD | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV50435153; called by muse, mutect2
- MMP16 | c.1591G>T p.G531C | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54171236; called by muse, mutect2, varscan2
- MMP20 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV52776296; called by muse, mutect2, varscan2
- MMRN1 | c.2391C>G p.N797K | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs981596032, COSV53338753; called by muse, mutect2, varscan2
- MRC2 | c.2034A>T p.K678N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57640880; called by muse, mutect2, varscan2
- MUC16 | c.31696G>C p.E10566Q | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.14); catalogued as COSV67474289; called by muse, mutect2, varscan2
- MUC16 | c.29537C>G p.T9846S | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); catalogued as COSV67474293; called by muse, mutect2, varscan2
- MUC5AC | c.927C>A p.H309Q | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.25); catalogued as COSV62254324; called by muse, mutect2
- MUC5B | c.12962C>A p.T4321N | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.267); catalogued as COSV71593115; called by muse, mutect2, varscan2
- MYH13 | c.3732G>C p.K1244N | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52832420; called by muse, mutect2, varscan2
- MYH2 | c.4684G>T p.G1562* | Nonsense Mutation (SNP) | VAF 32/220 reads (15%) | catalogued as COSV55440845; called by muse, mutect2, varscan2
- MYO1C | c.586A>T p.S196C (on ENST00000648651 / NM_001080779.2; = p.S161C on NM_033375.5) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62999542; called by muse, mutect2, varscan2
- MYOCD | c.863G>C p.R288P | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58505663; called by muse, mutect2, varscan2
- MYT1 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV60507617; called by muse, mutect2, varscan2
- NAA16 | c.153G>C p.M51I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65065520; called by muse, mutect2
- NELL2 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61577497; called by muse, mutect2, varscan2
- NOL6 | c.1779G>T p.Q593H | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53042866; called by muse, mutect2, varscan2
- NPAP1 | c.2910T>G p.S970R | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.136); catalogued as COSV61508148; called by muse, mutect2, varscan2
- NPHS2 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as COSV62635747; called by muse, mutect2, varscan2
- NRXN1 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV100454322; called by muse, mutect2, varscan2
- NTNG1 | c.1166A>C p.H389P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV64273648, COSV64278211; called by muse, mutect2, varscan2
- NUDCD1 | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53457805; called by muse, mutect2
- NUFIP2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV56604041; called by muse, mutect2, varscan2
- OCA2 | c.1823_1824insA p.Q609Pfs*8 | Frame Shift Ins (INS) | VAF 31/243 reads (13%) | catalogued as COSV100667355; called by mutect2, pindel, varscan2
- OCA2 | c.1594T>A p.W532R | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV62348883; called by muse, mutect2, varscan2
- OMD | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV65020284; called by muse, mutect2, varscan2
- OR11H4 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV59560447; called by muse, mutect2, varscan2
- OR1N1 | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59196001; called by muse, mutect2, varscan2
- OR2L3 | c.619G>T p.V207L | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63455469; called by muse, mutect2
- OR2M5 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 202/753 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV63546498; called by muse, mutect2, varscan2
- OR2T34 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV60899605, COSV60900803; called by muse, mutect2, varscan2
- OR2T6 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV63216560; called by muse, mutect2
- OR4C3 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV60587131; called by muse, mutect2, varscan2
- OR4P4 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV58922531; called by muse, mutect2, varscan2
- OR51D1 | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62914311, COSV62914347; called by muse, mutect2, varscan2
- OR51L1 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.994); catalogued as rs150980273; called by muse, mutect2, varscan2
- OR5L1 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61734348; called by muse, mutect2, varscan2
- OR5M3 | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs973923348, COSV56567255; called by muse, mutect2, varscan2
- OR6F1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57468272, COSV57469037; called by muse, mutect2, varscan2
- OR8B8 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV60144900; called by muse, mutect2, varscan2
- OVCH1 | c.2842G>A p.G948S | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs745853862, COSV58964568; called by muse, varscan2
- OVCH1 | c.2789C>A p.T930N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV58964580; called by muse, varscan2
- P2RY8 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67177610; called by muse, mutect2
- PACSIN3 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54066424; called by muse, mutect2, varscan2
- PASD1 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV64854226, COSV64855802; called by muse, mutect2, varscan2
- PASD1 | c.1872C>G p.F624L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as COSV64855806; called by muse, mutect2, varscan2
- PAX2 | c.998T>A p.M333K (on ENST00000428433 / NM_003987.5; = p.M310K on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV62291582; called by muse, mutect2, varscan2
- PAX4 | c.471T>A p.S157R | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV58387547, COSV58389431; called by muse, mutect2, varscan2
- PAX7 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV64750877; called by muse, mutect2, varscan2
- PCDH11X | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.927); catalogued as COSV53476362; called by muse, varscan2
- PCDH15 | c.2869-1G>A p.X957_splice | Splice Site (SNP) | VAF 17/119 reads (14%) | catalogued as COSV100227223, COSV57332878; called by muse, mutect2
- PCDHB16 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV53364278, COSV53372418; called by muse, mutect2, varscan2
- PCDHB7 | c.1978G>C p.V660L | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.33); catalogued as COSV50772567, COSV50778733; called by muse, mutect2
- PCNX2 | c.1214G>T p.S405I | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV50814344; called by muse, mutect2, varscan2
- PDE10A | c.1105T>A p.Y369N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.679); catalogued as COSV63050056; called by muse, mutect2, varscan2
- PDGFRA | c.3096G>T p.E1032D | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57269695; called by muse, mutect2, varscan2
- PDSS2 | c.927G>C p.M309I | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV64655629; called by muse, mutect2, varscan2
- PEG3 | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV55637266; called by muse, mutect2, varscan2
- PEX12 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56778315; called by muse, varscan2
- PID1 | c.144G>T p.M48I (on ENST00000354069 / NM_001330156.1; = p.M46I on NM_017933.5) | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.885); catalogued as COSV62477267; called by muse, mutect2, varscan2
- PKHD1 | c.6972C>G p.I2324M | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV61881760; called by muse, mutect2, varscan2
- PLEKHH2 | c.4378C>T p.P1460S | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV56756212; called by muse, mutect2, varscan2
- POLE | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV57683006; called by muse, mutect2, varscan2
- POLR2B | c.3346G>T p.V1116F | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV55274114, COSV55274330; called by muse, mutect2, varscan2
- POT1 | c.1430G>C p.R477T | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV62930355, COSV62934021; called by muse, mutect2, varscan2
- PPP1R7 | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV52145477; called by muse, mutect2, varscan2
- PPP2R2A | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV60097585; called by muse, mutect2, varscan2
- PRKG2 | c.462-2A>T p.X154_splice | Splice Site (SNP) | VAF 31/221 reads (14%) | catalogued as COSV52326354; called by muse, mutect2, varscan2
- PTCHD4 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV59788020; called by muse, mutect2, varscan2
- PTK2 | c.2290C>T p.Q764* | Nonsense Mutation (SNP) | VAF 24/192 reads (13%) | catalogued as COSV61787476; called by muse, mutect2, varscan2
- PTPN9 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60724282; called by muse, mutect2, varscan2
- PTPRD | c.3589G>T p.D1197Y | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV61956710; called by muse, mutect2, varscan2
- RALGPS1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52224631; called by muse, mutect2, varscan2
- RALYL | c.451C>G p.R151G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV72822111, COSV72822148; called by muse, mutect2, varscan2
- RASSF8 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV51454009, COSV51455341; called by muse, mutect2, varscan2
- REST | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58361264, COSV58361801; called by muse, mutect2, varscan2
- RGS20 | c.706C>A p.H236N (on ENST00000297313 / NM_170587.4; = p.H89N on NM_003702.4) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52018327; called by muse, mutect2
- RUFY2 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.962); catalogued as COSV61191497; called by muse, mutect2
- RYR3 | c.11063C>A p.S3688Y (on ENST00000389232; = p.S3689Y on NM_001036.6) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV66795325; called by muse, mutect2, varscan2
- SAMD9L | c.160del p.D54Tfs*3 | Frame Shift Del (DEL) | VAF 23/240 reads (10%) | catalogued as COSV59083080; called by mutect2, pindel, varscan2
- SEMA6D | c.2255G>A p.G752E (on ENST00000316364 / NM_153618.2; = p.G690E on NM_020858.2) | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV60379103; called by muse, mutect2, varscan2
- SERPINA6 | c.826G>T p.V276F | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58585717; called by muse, mutect2, varscan2
- SERPINB3 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52192213; called by muse, mutect2
- SERPINB8 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV54639938; called by muse, mutect2, varscan2
- SGCA | c.251A>T p.H84L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV56249713; called by muse, mutect2, varscan2
- SLC12A2 | c.3154T>A p.C1052S | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV52472668; called by muse, mutect2, varscan2
- SLC44A1 | c.761-1G>C p.X254_splice | Splice Site (SNP) | VAF 17/162 reads (10%) | catalogued as COSV58265339; called by muse, mutect2, varscan2
- SLC5A4 | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 54/382 reads (14%) | catalogued as COSV56671279, COSV56671556; called by muse, mutect2, varscan2
- SLC6A19 | c.767C>A p.T256K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs375879452, COSV58672096, COSV58675414; called by muse, mutect2, varscan2
- SLC6A5 | c.2056C>G p.P686A | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54228152; called by muse, mutect2
- SLC7A7 | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV53537439; called by muse, mutect2, varscan2
- SNRNP48 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as COSV60939817; called by muse, mutect2, varscan2
- SPAG16 | c.1390del p.D464Mfs*18 | Frame Shift Del (DEL) | VAF 14/144 reads (10%) | catalogued as COSV100531284; called by mutect2, pindel
- SPANXN3 | c.44G>C p.S15T | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV65140477; called by muse, mutect2, varscan2
- SPIRE1 | c.1356G>C p.K452N (on ENST00000409402 / NM_001128626.2; = p.K438N on NM_020148.3) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.234); catalogued as COSV59157949; called by muse, mutect2, varscan2
- SPOCK3 | c.689C>A p.T230K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.341); catalogued as COSV62722389; called by muse, mutect2, varscan2
- SPTA1 | c.6897C>A p.C2299* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as COSV63755124; called by muse, mutect2
- SSX3 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV53644495; called by muse, mutect2, varscan2
- STARD10 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV58325889; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3176C>T p.T1059I | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV59132255; called by muse, mutect2, varscan2
- STOX1 | c.2363G>T p.R788M | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.72); catalogued as COSV53815652; called by muse, mutect2, varscan2
- SYN3 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV60510415; called by muse, mutect2
- SYNE3 | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62080249, COSV62084242; called by muse, mutect2, varscan2
- SYNPO2 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61112906; called by muse, mutect2
- TAF1L | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 96/565 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774366817, COSV54261717; called by muse, mutect2, varscan2
- TBC1D1 | c.2322G>T p.W774C | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790920; called by muse, mutect2, varscan2
- TBC1D1 | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 26/262 reads (10%) | catalogued as COSV99790924; called by muse, mutect2
- TBC1D16 | c.1028A>T p.D343V | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV60478685; called by muse, mutect2, varscan2
- TDRD5 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV54242966; called by muse, mutect2, varscan2
- TICRR | c.1177-1G>T p.X393_splice | Splice Site (SNP) | VAF 10/78 reads (13%) | catalogued as COSV51542648; called by muse, mutect2
- TLL2 | c.1753C>A p.H585N | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100780550, COSV63573287, COSV63575956; called by muse, mutect2
- TLN2 | c.1645C>G p.Q549E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV60891090; called by muse, mutect2, varscan2
- TMEM132B | c.3073A>T p.K1025* | Nonsense Mutation (SNP) | VAF 34/126 reads (27%) | catalogued as COSV54757343; called by muse, mutect2, varscan2
- TMEM168 | c.135G>T p.L45F | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs752852979, COSV57181167; called by muse, mutect2, varscan2
- TMPRSS3 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 25/305 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52304286; called by muse, mutect2
- TP53INP1 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV61331620, COSV61331826; called by muse, mutect2
- TPX2 | c.2138A>G p.H713R | Missense Mutation (SNP) | VAF 154/485 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778633428, COSV55920304; called by muse, mutect2, varscan2
- TRAM1L1 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV60292107, COSV60292308; called by muse, mutect2, varscan2
- TRIM29 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 63/317 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs767499147, COSV59280375, COSV59280957; called by muse, mutect2, varscan2
- TRIM69 | c.1499A>T p.Q500L (on ENST00000329464 / NM_182985.5; = p.Q341L on NM_080745.5) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV57804112; called by muse, mutect2, varscan2
- TUBA8 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV57813279; called by muse, mutect2, varscan2
- UGT2B7 | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV59443915; called by muse, mutect2, varscan2
- USH2A | c.7657T>A p.W2553R | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56386959; called by muse, mutect2, varscan2
- USH2A | c.5399G>C p.W1800S | Missense Mutation (SNP) | VAF 168/716 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM149920, COSV56386971; called by muse, varscan2
- USH2A | c.5354C>G p.T1785R | Missense Mutation (SNP) | VAF 94/896 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56386983; called by muse, varscan2
- USH2A | c.3800C>T p.A1267V | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs768141777, COSV56384831; called by muse, mutect2, varscan2
- USP32 | c.4753G>T p.D1585Y | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56270778; called by muse, mutect2, varscan2
- USP9X | c.5015G>T p.R1672M | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61070852; called by muse, mutect2, varscan2
- USPL1 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV55000457; called by muse, mutect2, varscan2
- VIRMA | c.4792A>G p.T1598A | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52586517; called by muse, mutect2, varscan2
- WDPCP | c.2191-1G>T p.X731_splice | Splice Site (SNP) | VAF 17/132 reads (13%) | catalogued as COSV99704738; called by muse, mutect2, varscan2
- WDR6 | c.1731C>G p.C577W | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.785); catalogued as COSV58245454; called by muse, mutect2, varscan2
- WIPI1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV50930357; called by muse, mutect2
- WWTR1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs763418690, COSV62291763; called by muse, mutect2, varscan2
- XIRP2 | c.3602A>T p.Q1201L (on ENST00000628543; = p.Q1376L on NM_152381.6) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54709516; called by muse, mutect2, varscan2
- YIPF1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50777696; called by muse, mutect2
- ZC3HAV1 | c.2018C>A p.S673Y | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV54297140; called by muse, mutect2, varscan2
- ZC3HAV1 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV54297154; called by muse, mutect2
- ZFPM2 | c.2190G>C p.Q730H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV65874291; called by muse, mutect2, varscan2
- ZNF479 | c.833T>A p.F278Y | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58639794; called by muse, mutect2, varscan2
- ZNF479 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV58639805; called by muse, mutect2, varscan2
- ZNF780A | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100575035, COSV61816868; called by muse, varscan2
- ZNF780A | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs557141470, COSV61815791; called by muse, varscan2
- ATR | c.6898-3del | Splice Region (DEL) | VAF 19/103 reads (18%) | called by mutect2, pindel, varscan2
- CCL14 | c.236G>T p.S79I (on ENST00000618404 / NM_032963.4; = p.S95I on NM_032962.4) | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- DYNC1H1 | c.9124_9126dup p.L3042dup | In Frame Ins (INS) | VAF 33/176 reads (19%) | called by mutect2, pindel, varscan2
- HEATR9 | c.252C>A p.H84Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, mutect2
- IGKV2D-28 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by mutect2, varscan2
- INSRR | c.2239del p.A747Qfs*28 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- OR3A2 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 17/150 reads (11%) | called by muse, varscan2
- PPRC1 | c.1219del p.L407Sfs*10 | Frame Shift Del (DEL) | VAF 33/306 reads (11%) | called by mutect2, pindel, varscan2
- RAB6D | c.555A>C p.R185S | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ROBO2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS4Y2 | c.272_274del p.S91del | In Frame Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- SPR | c.402del p.T135Lfs*5 | Frame Shift Del (DEL) | VAF 29/241 reads (12%) | called by mutect2, pindel, varscan2
- ABCG1 | c.894G>T p.R298= | Silent (SNP) | VAF 53/411 reads (13%) | catalogued as COSV59206032; called by muse, mutect2, varscan2
- ADGRG4 | c.6919C>A p.R2307= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs376547734, COSV54959019; called by muse, mutect2, varscan2
- ANKRD26 | c.1266T>C p.S422= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV65795301; called by muse, mutect2, varscan2
- ANO6 | c.1290G>A p.V430= | Silent (SNP) | VAF 49/222 reads (22%) | catalogued as rs1308184708, COSV57662771; called by muse, mutect2, varscan2
- APMAP | c.180G>T p.L60= | Silent (SNP) | VAF 35/196 reads (18%) | catalogued as COSV54174675; called by muse, mutect2, varscan2
- ARHGAP25 | c.507A>G p.E169= (on ENST00000409202 / NM_001007231.3; = p.E161= on NM_014882.3) | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV54903808; called by muse, mutect2, varscan2
- ATP11C | c.2982A>G p.G994= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1297443682, COSV59566722; called by muse, mutect2, varscan2
- ATP8B2 | c.3243C>T p.P1081= (on ENST00000672630; = p.P1048= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 66/346 reads (19%) | catalogued as COSV59246625; called by muse, mutect2, varscan2
- BRINP2 | c.2268G>T p.V756= | Silent (SNP) | VAF 25/185 reads (14%) | catalogued as COSV64178207; called by muse, mutect2, varscan2
- C1orf105 | c.441C>A p.P147= | Silent (SNP) | VAF 54/526 reads (10%) | catalogued as COSV62959495; called by muse, varscan2
- C1orf226 | c.444G>A p.L148= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV63395721; called by muse, mutect2, varscan2
- CASP4 | c.198T>C p.R66= | Silent (SNP) | VAF 38/228 reads (17%) | catalogued as rs1260480052, COSV67744533; called by muse, mutect2, varscan2
- CD1E | c.693T>C p.H231= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as rs1226448121, COSV63771412; called by muse, mutect2, varscan2
- CDH20 | c.279C>A p.S93= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV53006176, COSV53011939; called by muse, mutect2
- CELSR2 | c.6909G>A p.T2303= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as rs150014940; called by muse, mutect2, varscan2
- CGNL1 | c.1047A>G p.S349= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs1360349045, COSV55569983; called by muse, mutect2, varscan2
- CNGA4 | c.981T>A p.P327= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as COSV66006266; called by muse, mutect2
- CNTNAP2 | c.492G>T p.L164= | Silent (SNP) | VAF 26/249 reads (10%) | catalogued as COSV62201645; called by muse, mutect2
- COL16A1 | c.570C>A p.S190= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV54708393; called by muse, mutect2
- CTSC | c.1092G>A p.L364= | Silent (SNP) | VAF 40/235 reads (17%) | catalogued as COSV57058536; called by muse, mutect2, varscan2
- CYYR1 | c.30A>T p.P10= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV54833623; called by muse, mutect2, varscan2
- DMRTA2 | c.942G>A p.R314= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV68672736; called by muse, mutect2, varscan2
- DNAI2 | c.969G>A p.L323= | Silent (SNP) | VAF 102/400 reads (26%) | catalogued as COSV56759550; called by muse, mutect2, varscan2
- DPEP2 | c.1431C>A p.A477= | Silent (SNP) | VAF 75/391 reads (19%) | catalogued as COSV52054913; called by muse, mutect2, varscan2
- ERBB2 | c.291G>A p.Q97= | Silent (SNP) | VAF 23/212 reads (11%) | catalogued as COSV54073487, COSV54085494; called by muse, mutect2, varscan2
- FAM107A | c.102G>T p.L34= | Silent (SNP) | VAF 28/192 reads (15%) | catalogued as COSV62980782; called by muse, mutect2, varscan2
- FAM163A | c.120C>A p.T40= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as COSV59203667, COSV59204251; called by muse, mutect2, varscan2
- FMN2 | c.2388C>A p.V796= | Silent (SNP) | VAF 50/184 reads (27%) | catalogued as COSV60435299; called by muse, mutect2, varscan2
- FOXP2 | c.993G>T p.S331= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV100646128, COSV63488109; called by muse, mutect2
- GALNT7 | c.1104C>T p.T368= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1332696812, COSV53931379; called by muse, mutect2, varscan2
- GFRA3 | c.684G>T p.G228= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV51229096, COSV99218344; called by muse, mutect2, varscan2
- GFRAL | c.744G>A p.V248= | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as rs748931694, COSV61232059; called by muse, mutect2, varscan2
- GHDC | c.723G>A p.R241= | Silent (SNP) | VAF 20/207 reads (10%) | catalogued as COSV56988516; called by muse, mutect2, varscan2
- GLI2 | c.759C>G p.P253= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as COSV58044478; called by muse, mutect2, varscan2
- GPC6 | c.378G>T p.R126= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV65515967; called by muse, mutect2, varscan2
- GPR12 | c.436C>T p.L146= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV67344476; called by muse, mutect2, varscan2
- GPR61 | c.867C>A p.L289= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as COSV63983960; called by muse, mutect2, varscan2
- GPRASP2 | c.2355G>A p.Q785= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV59991699; called by muse, mutect2, varscan2
- H2BW1 | c.468C>T p.S156= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs370071971, COSV54220528; called by muse, mutect2, varscan2
- HOXA5 | c.480G>A p.A160= | Silent (SNP) | VAF 34/238 reads (14%) | catalogued as rs202017218, COSV56073789; called by muse, mutect2
- HPS4 | c.870A>T p.T290= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV61103980; called by muse, mutect2, varscan2
- HYDIN | c.14979C>A p.P4993= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as COSV66639727; called by muse, mutect2, varscan2
- IL7R | c.1248C>G p.P416= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as COSV100286448, COSV57409599; called by muse, mutect2, varscan2
- IL9R | c.441G>C p.L147= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV99729573; called by muse, mutect2
- ITGAD | c.1779C>A p.L593= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV66758485; called by muse, mutect2, varscan2
- ITGAD | c.2595C>A p.P865= | Silent (SNP) | VAF 49/291 reads (17%) | catalogued as COSV66758486; called by muse, mutect2, varscan2
- KCNA6 | c.1038G>T p.L346= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs757378869, COSV54976019; called by muse, mutect2, varscan2
- KRBA1 | c.672G>T p.R224= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV55442140; called by muse, mutect2, varscan2
- LPL | c.1209C>G p.L403= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV60931517; called by muse, mutect2, varscan2
- LRRC8C | c.1735C>T p.L579= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as COSV64998934; called by muse, mutect2
- LRRK2 | c.3066A>C p.A1022= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as COSV54157185; called by muse, mutect2, varscan2
- MATN1 | c.201C>A p.V67= | Silent (SNP) | VAF 36/225 reads (16%) | catalogued as COSV65650868; called by muse, mutect2, varscan2
- MMP16 | c.729A>T p.V243= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV54171257; called by muse, mutect2
- MS4A6E | c.30C>G p.T10= | Silent (SNP) | VAF 27/204 reads (13%) | catalogued as COSV55727249; called by muse, mutect2, varscan2
- MUC16 | c.11475A>C p.P3825= | Silent (SNP) | VAF 63/395 reads (16%) | catalogued as COSV101202441, COSV67474302; called by muse, mutect2, varscan2
- MYH6 | c.5313G>A p.L1771= | Silent (SNP) | VAF 25/262 reads (10%) | catalogued as COSV59306383; called by muse, mutect2, varscan2
- MYOM3 | c.303G>A p.R101= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1201152247, COSV58395469; called by muse, varscan2
- NALCN | c.2109C>T p.I703= | Silent (SNP) | VAF 26/197 reads (13%) | catalogued as rs1019776644, COSV51943405; called by muse, mutect2, varscan2
- NIBAN3 | c.1959T>C p.S653= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as COSV53109837; called by muse, mutect2, varscan2
- NLRP2 | c.2955C>T p.V985= | Silent (SNP) | VAF 48/245 reads (20%) | catalogued as COSV54756469; called by muse, mutect2, varscan2
- NOTCH4 | c.1842C>A p.L614= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as COSV66681582; called by muse, mutect2, varscan2
- NYAP2 | c.1158C>T p.H386= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV56008423; called by muse, mutect2
- OR10G4 | c.321G>T p.G107= | Silent (SNP) | VAF 40/388 reads (10%) | catalogued as COSV57978507; called by muse, varscan2
- OR10X1 | c.903C>T p.I301= | Silent (SNP) | VAF 74/331 reads (22%) | catalogued as COSV63767237, COSV63767322; called by muse, mutect2, varscan2
- OR6V1 | c.168C>G p.P56= | Silent (SNP) | VAF 66/460 reads (14%) | catalogued as COSV69237394; called by muse, mutect2, varscan2
- OSBPL10 | c.675A>T p.A225= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV67340627; called by muse, mutect2, varscan2
- PARD3B | c.636A>T p.P212= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV62515986; called by muse, mutect2, varscan2
- PCDHAC2 | c.168G>A p.A56= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs782780798, COSV53851024; called by muse, mutect2, varscan2
- PDE6H | c.243G>A p.G81= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV56760841; called by muse, mutect2, varscan2
- PKHD1L1 | c.435C>T p.T145= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as COSV65745649; called by muse, mutect2
- PKHD1L1 | c.2997A>G p.L999= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV65737613, COSV65745656; called by muse, mutect2, varscan2
- PKHD1L1 | c.8304G>T p.G2768= | Silent (SNP) | VAF 24/216 reads (11%) | catalogued as COSV65743060, COSV65745659; called by muse, mutect2, varscan2
- PKNOX1 | c.813G>T p.T271= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV52336977; called by muse, mutect2, varscan2
- PLA2G6 | c.2412C>T p.L804= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1298842870, COSV59270913; called by muse, mutect2
- PRMT1 | c.702G>A p.E234= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV67159810; called by muse, mutect2, varscan2
- PTPRC | c.408C>T p.L136= | Silent (SNP) | VAF 46/550 reads (8%) | catalogued as rs1239293392, COSV61414078; called by muse, mutect2
- PTPRZ1 | c.288T>C p.H96= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as COSV66439364; called by muse, mutect2, varscan2
- RSBN1 | c.1701C>T p.T567= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs960914700, COSV54733109; called by muse, mutect2, varscan2
- SALL2 | c.972C>T p.T324= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs1181391004, COSV58103963; called by muse, mutect2, varscan2
- SCD5 | c.351C>T p.S117= | Silent (SNP) | VAF 10/131 reads (8%) | catalogued as rs936938166, COSV51103065; called by muse, mutect2
- SERTAD2 | c.258C>T p.F86= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs1261100399, COSV57640538; called by muse, mutect2, varscan2
- SH3BP5L | c.657C>T p.I219= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs759676523, COSV63539441; called by muse, mutect2
- SLAIN2 | c.846C>G p.A282= | Silent (SNP) | VAF 27/222 reads (12%) | catalogued as COSV51907521; called by muse, mutect2, varscan2
- SLC5A1 | c.1077T>A p.V359= | Silent (SNP) | VAF 35/228 reads (15%) | catalogued as COSV56686288; called by muse, mutect2, varscan2
- SLC6A15 | c.549T>A p.P183= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV57022416, COSV57025231; called by muse, mutect2, varscan2
- SLC6A5 | c.507G>T p.V169= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV54228143; called by muse, mutect2, varscan2
- SLC8A1 | c.36C>A p.T12= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs747163311, COSV60485134; called by muse, mutect2, varscan2
- SMARCAD1 | c.1821G>T p.A607= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs111425618, COSV62774135, COSV62774909; called by muse, varscan2
- SYDE2 | c.1467T>C p.N489= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV52316092; called by muse, mutect2, varscan2
- TAS2R16 | c.690C>T p.A230= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as rs187186713, COSV50797402, COSV50799191; called by muse, mutect2, varscan2
- TFDP3 | c.1149A>G p.P383= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV59537450; called by muse, mutect2
- THADA | c.1341G>A p.L447= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV57686145; called by muse, mutect2, varscan2
- TTN | c.23082A>G p.S7694= (on ENST00000591111; = p.S6767= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/300 reads (10%) | catalogued as COSV60137327; called by muse, mutect2
- UGDH | c.669A>G p.A223= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV57098118; called by muse, varscan2
- VAC14 | c.1626G>A p.R542= | Silent (SNP) | VAF 10/220 reads (5%) | catalogued as COSV55754310; called by muse, mutect2
- WDR89 | c.813A>G p.E271= | Silent (SNP) | VAF 64/314 reads (20%) | catalogued as COSV50827001; called by muse, mutect2, varscan2
- XIRP2 | c.8436G>A p.L2812= (on ENST00000628543; = p.L2987= on NM_152381.6) | Silent (SNP) | VAF 23/216 reads (11%) | catalogued as COSV54709527, COSV99747742; called by muse, mutect2, varscan2
- ZNF536 | c.2151C>A p.P717= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV62826482; called by muse, mutect2, varscan2
- ZNF780A | c.225G>T p.R75= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV100575034; called by muse, varscan2
- RNU6-104P | chr8:43302055 C>G | 5'Flank (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472260 G>T | 3'Flank (SNP) | VAF 27/210 reads (13%) | called by muse, mutect2, varscan2
